Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA5P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA5P-01A (Primary Tumor).

[page 1 of 2]
Histopathology

Histopathology

Specimen Comments

SPECIMEN

- A. Bladder and prostate
- B. Right lymph nodes
- C. Left obturator nodes
- D. Left external iliac nodes
- E. Left internal iliac nodes
- F. Left ureteric resection margin
- G. Right ureteric resection margin

ICD O-3
Carcinoma, urothelial NOS 8120/3
Site: Bladder, posterior wall 0674
JH 4/30/14

CLINICAL DETAILS

Bladder cancer - cystectomy

MACROSCOPY

- A. Cystoprostatectomy consisting prostate (70mm x 50mm x 32mm), bladder (82 x 86 x 50mm) and perivesical fat. The prostate shows numerous nodules. The left inferior lateral wall contains a firm exfiltrate flat mass, measuring 18 x 15 mm in maximum dimension, which on sectioning appears to extend in to perivesical fat. Infiltrates to a depth of 11mm. No lymph nodes identified in perivesical fat. A1 = urethral SRM, A2 = right lobe of prostate, A3 = left lobe of prostate, A4 = prostate and urethra, A5 - A7 = tumour, A8 = dome, A9 = right lateral wall, A10 = posterior wall, A11 = anterior wall, A12 = trigone.
- B. Multiple fatty fragments, measuring 80 x 75 x 25mm, with 5 lymph nodes, the largest measuring up to 32mm in maximum dimension. B1 + B2 = 1 LN, B3 = 1 LN, B4 - 6 = 1 LN, B7 - 9 = 1 LN, B10 = 1 LN, B11 = 1 LN, B12 = ?LN
- C. Fatty tissue with 2 lymph nodes, the larger measuring 56mm. C = 1LN, C2 - 7 = other lymph node
- D. Fatty mass with 2 lymph nodes, larger measuring up to 42mm. Other lymph node is a cream nodule of metastatic tumour, 20mm in maximum dimension. D1 + D2 = 1 LN, D3-4 = other, D5 = ?LN
- E. Fatty tissue with a lymph node, 26mm in maximum dimension. No obvious tumour seen. E1 - 3 = LN, E4 = ?LN
- F. Piece of tissue measuring 11 x 5 x 2mm. No obvious ureter seen.
- G. Cut - opened fragment of ureter, up to 4mm

MICROSCOPY

Part A:

Sections from the macroscopically identified lesion in the left infero-lateral wall confirm a poorly-differentiated invasive urothelial carcinoma, extending to the outer half of the muscularis propria. The tumour does not extend in to the perivesical fat.

Sections from the trigone and from the posterior wall contain further separate foci of invasive urothelial carcinoma with the lesion in the posterior wall (A10) showing micropapillary change.

Random sections taken from the rest of the bladder show extensive carcinoma in situ.

There is no carcinoma in situ or urothelial carcinoma affecting the prostatic urethra or the prostatic ducts.

Sections from the prostate show a small (up to 5mm) focus of organ-confined microacinar adenocarcinoma of the prostate with a Gleason pattern 3, involving the left lobe. No extraprostatic or perineural invasion is noted. The urethral surgical resection margin is morphologically normal.

Part B (right lymph nodes):

7 lymph nodes identified: no metastatic carcinoma

Part C (left obturator nodes):

2 lymph nodes: no metastatic carcinoma

[page 2 of 2]
Part D (left external iliac nodes):

3 nodes identified; one with metastatic urothelial carcinoma. There is no extracapsular extension.

Part E (left internal iliac nodes):

A single node identified with metastatic carcinoma. No extracapsular extension noted.

Part F (left ureteric resection margin):

All the tissue was processed and contains some thick muscle wall, which is most likely ureteric. There is no invasive tumour. No urothelium is included.

Part G (right ureteric resection margin):

This is morphologically normal ureter.

SUMMARY (Parts A - G)

Bladder: High grade urothelial carcinoma pT2b pN2 R0

Prostate: Gleason sum score 6, pT2 pN0 R0

Ref:

Pathologists -

Source: NCI Genomic Data Commons file c492d496-c83b-4b7b-8074-332698dc404a (TCGA-ZF-AA5P.BB68912E-1368-47BF-BC76-0C1C8532E6BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).